Gene-level copy-number profile of tumor specimen C3L-04270-59 from CPTAC case C3L-04270, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 71.3 years (26,048 days).
Specimen C3L-04270-59: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 73db6297-2863-4b64-8a1d-4aceb02fe767.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-04270-52 (buccal cell normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,220 have no estimate.
https://portal.gdc.cancer.gov/files/2a91d22e-7da5-47b9-b7da-372c745c2fa5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 8,252; copy number 2: 50,120; copy number 3: 18.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:161,907,111–163,519,354, 12 genes: LINC01202, GABRG2, AC113414.1, RNU6-164P, ARL2BPP5, MRPL57P6, AC008723.1, CCNG1, NUDCD2, HMMR, HMMR-AS1, MAT2B.
- chr12:11,351,823–11,395,566, 1 gene (within-gene range 0–1): PRB1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 8,252. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
